TCGA case TCGA-XM-A8RD — Thymoma (TCGA-THYM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Thymic Epithelial Neoplasms; Primary site: Thymus; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/68d2ab61-50fc-41e8-b3ee-75c70f0f4369

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 69 years; Vital status: Alive.

Diagnoses (3)
1. Thymoma, type B2, malignant (the primary disease): ICD-O-3 morphology code: 8584/3; ICD-10 code: C37; Tissue or organ of origin: Thymus; Site of resection or biopsy: Thymus; Classification of tumor: primary; Age at diagnosis: 69.5 years (25,402 days); Year of diagnosis: 2010; Method of diagnosis: Surgical Resection; Masaoka stage: Stage IIa; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,546 days (4.2 years).
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; Tissue or organ of origin: Thyroid gland; Classification of tumor: Synchronous primary; Age at diagnosis: 69.4 years (25,348 days); Days to diagnosis: -54 days.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 91 days; Treatment anatomic sites: Thyroid.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Levothyroxine Sodium; Treatment anatomic sites: Body, total.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Thyroid.
   Recorded as not given: Pharmaceutical Therapy, NOS (Levothyroxine Sodium) to Body, total; Radiation Therapy, NOS.
3. Basal cell carcinoma, NOS: ICD-O-3 morphology code: 8090/3; Tissue or organ of origin: Head, face or neck, NOS; Classification of tumor: Prior primary.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 1,231 days (3.4 years); Disease response: Tumor Free.
- Days to follow up: 1,546 days (4.2 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 58 kg; Height: 163 cm; BMI: 21.8.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-XM-A8RD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 350 mg.
  Slide TCGA-XM-A8RD-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-XM-A8RD-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-XM-A8RD-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Stage record: Masaoka stage: IIa.
- Primary pathology, Histological type list: Histologic diagnosis: Thymoma, Type B2.
- Primary pathology: Method initial path diagnosis: Video-assisted Thorascopic Surgery (VATS); History myasthenia gravis: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy histological type: Thyroid Papillary Carcinoma - Other, specify; Other malignancy histological type text: Papillary Thyroid Cancer.
- Other malignancy form 1, Surgery: Other malignancy surgery type: Partial Thyroidectomy.
- Other malignancy form 1, Drug treatment: Pharmaceutical therapy extent: Systemic.
- Other malignancy form 1, Drug treatment, Administered drug: Pharmaceutical therapy drug name: Synthroid.
- Other malignancy form 2: Malignancy type: Synchronous Malignancy; Other malignancy histological type: Thyroid Papillary Carcinoma - Other, specify; Other malignancy histological type text: Papillary Thyroid microcarinoma.
- Other malignancy form 2, Surgery: Other malignancy surgery type: Total Thyroidectomy.
- Other malignancy form 2, Drug treatment, Administered drug: Pharmaceutical therapy drug name: synthroid.
- Other malignancy form 3: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Head - face or neck, NOS; Other malignancy histological type: Basal Cell Carcinoma.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,546 days; disease-specific survival: no event (censored), 1,546 days; progression-free interval: no event (censored), 1,546 days.
